Somatic mutation profile of tumor specimen 0DVPOJ from CCDI case PBCMAD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.1 years (385 days).
Specimen 0DVPOJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 547ef6b6-a93b-4b2c-ab3b-80a52d2b1a31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVPP1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/485d8467-fa38-4752-93a8-b87c91a76c0c

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDHB2 | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); catalogued as rs1348797529; called by muse, mutect2, varscan2
- SKIV2L | c.1784C>T p.S595L | Missense Mutation (SNP) | VAF 87/436 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.138); catalogued as rs867606706, COSV64814131; called by muse, mutect2, varscan2
- AL645922.1 | c.350C>A p.S117* | Nonsense Mutation (SNP) | VAF 63/274 reads (23%) | called by muse, mutect2, varscan2
- IFNLR1 | c.494A>C p.E165A | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MTTP | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- PLEC | c.8706C>A p.H2902Q (on ENST00000322810 / NM_201380.4; = p.H2792Q on NM_000445.5) | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TLR2 | c.880A>C p.N294H | Missense Mutation (SNP) | VAF 17/257 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2
- AQP7 | c.681G>A p.P227= | Silent (SNP) | VAF 45/176 reads (26%) | catalogued as rs116294914; called by muse, mutect2, varscan2
- CRLF2 | c.1068C>T p.I356= | Silent (SNP) | VAF 24/311 reads (8%) | catalogued as rs1300768114; called by muse, mutect2
- IL6 | c.165A>G p.K55= | Silent (SNP) | VAF 23/706 reads (3%) | called by muse, mutect2
- PDLIM2 | c.882-72del | Intron (DEL) | VAF 4/23 reads (17%) | called by mutect2, varscan2
